Somatic mutation profile of tumor specimen MMRF_1982_1_BM_CD138pos (aliquot MMRF_1982_1_BM_CD138pos_T1_KHS5U_L08063) from MMRF case MMRF_1982, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.3 years (19,112 days).
Specimen MMRF_1982_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fa09f16-2f4a-4907-8cb6-0aad2447ed2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1982_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1982_1_PB_Whole_C2_KHS5U_L08064; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0795d477-ecf4-4f3b-a69e-3b4b1e8dde10

The open-access MAF lists 71 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 28, Missense Mutation 19, Intron 9, Silent 8, 3'Flank 2, Nonsense Mutation 2, RNA 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASTN1 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as rs1345907735, COSV56075116; called by muse, mutect2, varscan2
- COL6A5 | c.7187A>G p.N2396S (on ENST00000312481; = p.N2392S on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/187 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs373345232; called by muse, mutect2, varscan2
- CYP27B1 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 86/175 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1033790241; called by muse, mutect2, varscan2
- IGHV1-69 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs375742751; called by muse, mutect2, varscan2
- IGHV2-70 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs377473012; called by muse, varscan2
- IGLV4-60 | c.80A>T p.Q27L | Missense Mutation (SNP) | VAF 88/172 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370017122; called by muse, varscan2
- IGLV4-60 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV101135230; called by muse, varscan2
- KCNN1 | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 75/231 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1406933882, COSV55838853; called by muse, mutect2, varscan2
- NASP | c.887A>T p.E296V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV63111833; called by muse, mutect2
- PCDHA13 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.224); catalogued as COSV56491140; called by muse, mutect2, varscan2
- SLC44A4 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 157/230 reads (68%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs374954632; called by muse, mutect2, varscan2
- USH2A | c.3317-1G>T p.X1106_splice | Splice Site (SNP) | VAF 33/72 reads (46%) | catalogued as COSV100239636; called by muse, mutect2, varscan2
- ATP2C1 | c.1872C>A p.H624Q | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- CDH19 | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 7/154 reads (5%) | called by muse, mutect2
- DBX2 | c.878A>G p.E293G | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM20C | c.1624C>T p.H542Y | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDA | c.1301A>G p.D434G | Missense Mutation (SNP) | VAF 207/413 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- MPP6 | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 81/292 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCB1 | c.1468T>G p.Y490D | Missense Mutation (SNP) | VAF 83/173 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PPP4R3C | c.116C>A p.S39* | Nonsense Mutation (SNP) | VAF 81/192 reads (42%) | called by muse, mutect2, varscan2
- SLIT2 | c.2327A>T p.Y776F | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ANK1 | c.1440C>T p.I480= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs758788802; called by muse, mutect2, varscan2
- IGHV2-70 | c.88C>T p.L30= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs377373222; called by muse, mutect2, varscan2
- IGHV2-70D | c.88C>T p.L30= | Silent (SNP) | VAF 19/80 reads (24%) | called by muse, varscan2
- IQSEC2 | c.3765G>A p.G1255= | Silent (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- MAGEC1 | c.1998T>C p.P666= | Silent (SNP) | VAF 84/204 reads (41%) | called by muse, mutect2, varscan2
- METTL1 | c.738T>A p.R246= | Silent (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- PARP3 | c.897G>A p.Q299= | Silent (SNP) | VAF 69/113 reads (61%) | called by muse, mutect2, varscan2
- SMAD4 | c.756A>G p.G252= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs1244121412; ClinVar: likely benign; called by muse, mutect2, varscan2
- AHCTF1 | c.*494A>T | 3'UTR (SNP) | VAF 94/188 reads (50%) | called by muse, mutect2, varscan2
- AL139807.1 | n.251-9439A>T | Intron (SNP) | VAF 58/177 reads (33%) | called by muse, mutect2, varscan2
- APOBEC3D | c.*596G>A | 3'UTR (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- BLOC1S4 | c.*780G>A | 3'UTR (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- BLOC1S4 | c.*781G>T | 3'UTR (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- C22orf23 | c.-9-28dup | Intron (INS) | VAF 91/225 reads (40%) | called by mutect2, pindel, varscan2
- ETV5 | c.-75+431A>T | Intron (SNP) | VAF 159/259 reads (61%) | called by muse, mutect2, varscan2
- FANCF | c.*1522A>G | 3'UTR (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- FRMD4B | c.*847T>A | 3'UTR (SNP) | VAF 54/72 reads (75%) | called by muse, mutect2
- HLTF | c.*439del | 3'UTR (DEL) | VAF 30/107 reads (28%) | called by mutect2, pindel, varscan2
- IFI44L | c.*783A>C | 3'UTR (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.-8T>G | 5'UTR (SNP) | VAF 28/89 reads (31%) | called by muse, varscan2
- IL17RB | c.*321T>C | 3'UTR (SNP) | VAF 49/175 reads (28%) | called by muse, mutect2, varscan2
- INTS6L | c.1287+1198T>G | Intron (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- IRX5 | c.250-285C>T | Intron (SNP) | VAF 59/124 reads (48%) | catalogued as rs935315528; called by muse, mutect2, varscan2
- KCNK2 | c.*730G>T | 3'UTR (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- KIAA0586 | c.4385-2982G>A | Intron (SNP) | VAF 73/79 reads (92%) | catalogued as rs893944120; called by muse, mutect2, varscan2
- KIAA1549 | c.*5118C>T | 3'UTR (SNP) | VAF 27/113 reads (24%) | catalogued as rs1036753268; called by muse, mutect2, varscan2
- L1TD1 | c.*110G>C | 3'UTR (SNP) | VAF 51/96 reads (53%) | called by muse, mutect2, varscan2
- LGR5 | c.*174A>G | 3'UTR (SNP) | VAF 34/80 reads (43%) | catalogued as rs760976962; called by muse, mutect2, varscan2
- LRRC10B | c.*255G>A | 3'UTR (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- LZTS1 | c.*2568T>C | 3'UTR (SNP) | VAF 52/137 reads (38%) | called by muse, mutect2, varscan2
- MCM4 | c.71-48C>T | Intron (SNP) | VAF 25/54 reads (46%) | called by muse, mutect2, varscan2
- MFAP3L | c.*4585T>C | 3'UTR (SNP) | VAF 30/78 reads (38%) | called by muse, mutect2, varscan2
- MIR137 | n.55G>A | RNA (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- MMP17 | c.423-298G>A | Intron (SNP) | VAF 68/132 reads (52%) | catalogued as rs541000494; called by muse, mutect2, varscan2
- OXTR | c.*1431C>T | 3'UTR (SNP) | VAF 9/211 reads (4%) | catalogued as rs943983684; called by muse, mutect2
- PCGF5 | c.*287T>C | 3'UTR (SNP) | VAF 32/77 reads (42%) | called by muse, mutect2, varscan2
- PCYT1A | c.*342A>C | 3'UTR (SNP) | VAF 43/118 reads (36%) | called by muse, mutect2, varscan2
- RALA | c.*1362T>C | 3'UTR (SNP) | VAF 30/78 reads (38%) | called by mutect2, varscan2
- SAR1B | c.*1408G>A | 3'UTR (SNP) | VAF 17/21 reads (81%) | catalogued as rs536315454; called by muse, varscan2
- SLITRK4 | chrX:143627849 A>G | 3'Flank (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- SOX30 | c.*554A>C | 3'UTR (SNP) | VAF 77/113 reads (68%) | called by muse, mutect2, varscan2
- TENM1 | c.*2371T>G | 3'UTR (SNP) | VAF 36/68 reads (53%) | called by muse, mutect2, varscan2
- TENM3 | c.*2059C>A | 3'UTR (SNP) | VAF 42/93 reads (45%) | called by muse, mutect2, varscan2
- TM4SF1 | c.*408C>A | 3'UTR (SNP) | VAF 37/116 reads (32%) | called by muse, mutect2, varscan2
- TRPV2 | c.*67T>G | 3'UTR (SNP) | VAF 53/113 reads (47%) | catalogued as rs1037978797; called by muse, mutect2, varscan2
- TSC22D1 | c.*447G>A | 3'UTR (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- UGT8 | c.*481G>A | 3'UTR (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2
- WHAMMP3 | chr15:22690455 T>C | 3'Flank (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- ZNF26 | c.34-1144T>C | Intron (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
